Somatic mutation profile of tumor specimen TCGA-EJ-A8FP-01A (aliquot TCGA-EJ-A8FP-01A-21D-A364-08) from TCGA case TCGA-EJ-A8FP, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 59.6 years (21,769 days).
Specimen TCGA-EJ-A8FP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b1a48bb4-67d2-4914-a8c2-aad5dff73f34.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EJ-A8FP-10A (Blood Derived Normal), aliquot TCGA-EJ-A8FP-10A-01D-A362-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8cea73e6-2f4d-4738-b638-27eca641fec3

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS10 | c.884C>T p.T295M | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as rs782715820, COSV54353466; called by muse, mutect2
- PPP1R16B | c.1000C>T p.R334W | Missense Mutation (SNP) | VAF 4/57 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55384180; called by muse, mutect2
- PRKG1 | c.1673C>T p.S558L | Missense Mutation (SNP) | VAF 4/77 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100907092; called by muse, mutect2
- ZNF207 | c.191C>T p.A64V | Missense Mutation (SNP) | VAF 4/92 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0.277); catalogued as COSV100340287, COSV58302437; called by muse, mutect2
- ANKRD11 | c.-1G>A | 5'UTR (SNP) | VAF 4/34 reads (12%) | catalogued as COSV99967994; called by muse, mutect2
